Somatic mutation profile of cancer-model specimen HCM-BROD-0328-C15-85A (3D Organoid, passage 4; aliquot HCM-BROD-0328-C15-85A-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0328-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen HCM-BROD-0328-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db8f0aac-3473-4164-b2e9-b058ca250bc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0328-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0328-C15-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f24f21aa-8dbe-45a8-8b34-ffaf4967a9e5

The open-access MAF lists 267 somatic variants for this specimen: 196 protein-altering or splice-affecting, 63 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 63, Nonsense Mutation 8, Frame Shift Del 5, Intron 4, 5'UTR 2, Splice Site 2, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs1344172059, COSV56859663; ClinVar: likely pathogenic; called by muse, mutect2
- CDKN2A | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 463/464 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339792331, COSV58682804, COSV58699096, COSV58719034; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 442/443 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABLIM3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs138526744; called by muse, mutect2, varscan2
- ACVRL1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 206/344 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1442565422; called by muse, mutect2, varscan2
- ADAP2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 336/851 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1316073001; called by muse, mutect2, varscan2
- ADAT3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 503/791 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777917952; called by muse, mutect2, varscan2
- AL592490.1 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 44/518 reads (8%) | catalogued as COSV69427993; called by muse, mutect2
- ARID3A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 252/778 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs749403652; called by muse, mutect2, varscan2
- ARPIN | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 219/593 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs762881310; called by muse, mutect2, varscan2
- ASTN1 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 167/390 reads (43%) | catalogued as COSV99923341; called by muse, mutect2, varscan2
- ATP10B | c.4197C>A p.H1399Q | Missense Mutation (SNP) | VAF 230/617 reads (37%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV59147206; called by muse, mutect2
- BCHE | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 136/365 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM147422, COSV52259411; called by muse, mutect2, varscan2
- C14orf119 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 195/370 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs747746207; called by muse, mutect2, varscan2
- COBL | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 132/336 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs200839538, COSV54362253; called by muse, mutect2, varscan2
- COL12A1 | c.6074G>A p.R2025H | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs34336755; called by muse, mutect2, varscan2
- CWC15 | c.253A>C p.T85P | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.216); catalogued as COSV54412662; called by muse, mutect2, varscan2
- DFFA | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1279195328; called by muse, mutect2, varscan2
- DPP9 | c.1997C>G p.T666R (on ENST00000598800; = p.T695R on NM_139159.5) | Missense Mutation (SNP) | VAF 149/439 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53593038; called by muse, mutect2, varscan2
- DPY19L2 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV60541558; called by muse, mutect2
- EIF4ENIF1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 216/475 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs947466155; called by muse, mutect2, varscan2
- ELOA | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.82); catalogued as rs1423390147, COSV69310011; called by muse, mutect2
- EPB41 | c.802G>A p.A268T (on ENST00000343067 / NM_001166005.2; = p.A59T on NM_004437.4) | Missense Mutation (SNP) | VAF 197/442 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs749554752; called by muse, mutect2, varscan2
- ERG | c.1054G>A p.D352N (on ENST00000398919 / NM_001243428.1; = p.D328N on NM_004449.4) | Missense Mutation (SNP) | VAF 253/512 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726685; called by muse, mutect2, varscan2
- EYS | c.2000G>C p.R667P | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs549456693, COSV65458786; called by muse, mutect2, varscan2
- FERMT2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 228/714 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58408166; called by muse, mutect2, varscan2
- FXYD5 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV54344191; called by muse, mutect2
- GPATCH1 | c.372A>G p.I124M | Missense Mutation (SNP) | VAF 296/519 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV50121515; called by muse, mutect2, varscan2
- HEATR6 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs780759321; called by muse, mutect2, varscan2
- HNF4A | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 290/496 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs765133569; called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.987); catalogued as rs755962148; called by muse, mutect2, varscan2
- IGLV4-60 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 367/632 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs551328414; called by muse, mutect2, varscan2
- KCNQ2 | c.2072G>A p.R691H (on ENST00000359125 / NM_172107.4; = p.R663H on NM_004518.6) | Missense Mutation (SNP) | VAF 591/832 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs773194884; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KLHL5 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 230/345 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV54678064; called by muse, mutect2, varscan2
- KNSTRN | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 166/394 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as COSV51109762; called by muse, mutect2, varscan2
- KPTN | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs760334759; called by muse, mutect2, varscan2
- LHX6 | c.1063G>C p.G355R (on ENST00000373755 / NM_001242334.2; = p.G384R on NM_014368.5) | Missense Mutation (SNP) | VAF 176/244 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1306790045, COSV104415141, COSV61346252; called by muse, mutect2, varscan2
- LILRA1 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 34/608 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV99252263; called by muse, mutect2
- LIPI | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.22); catalogued as rs773334224, COSV60709527; called by muse, mutect2, varscan2
- LTBP2 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 213/920 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs767990421; called by muse, mutect2, varscan2
- MGAT5B | c.1458C>A p.N486K (on ENST00000569840 / NM_001199172.2; = p.N484K on NM_144677.3) | Missense Mutation (SNP) | VAF 177/278 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1406372746; called by muse, mutect2, varscan2
- MPIG6B | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 287/510 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as COSV65389516; called by muse, mutect2, varscan2
- MYO16 | c.4972G>A p.A1658T | Missense Mutation (SNP) | VAF 204/664 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); catalogued as COSV62758336; called by muse, mutect2, varscan2
- NAALADL1 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 73/665 reads (11%) | catalogued as rs761452218; called by muse, mutect2, varscan2
- NOP2 | c.725G>A p.R242Q (on ENST00000322166 / NM_001258308.2; = p.R238Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/830 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370611159; called by muse, mutect2, varscan2
- NPR2 | c.2845C>T p.R949* | Nonsense Mutation (SNP) | VAF 363/363 reads (100%) | catalogued as rs1452208078; called by muse, mutect2, varscan2
- OR10Q1 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.29); catalogued as rs187146398; called by muse, mutect2, varscan2
- PCDH9 | c.3324C>A p.N1108K (on ENST00000377865 / NM_203487.3; = p.N1074K on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV60546663; called by muse, mutect2, varscan2
- PCDHA7 | c.1189T>G p.L397V | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs782594410, COSV65343154; called by muse, mutect2, varscan2
- PKHD1 | c.8065G>A p.D2689N | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776855458; called by muse, mutect2, varscan2
- PLCD3 | c.1448A>C p.K483T | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59560867; called by muse, varscan2
- PPFIA4 | c.2714G>A p.R905K (on ENST00000447715; = p.R906K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as rs761165262; called by muse, mutect2, varscan2
- PPIL2 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 464/824 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs1484190629; called by muse, mutect2, varscan2
- PPIL6 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs774828409; called by muse, mutect2, varscan2
- PTPRR | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs368662426; called by muse, mutect2, varscan2
- RARS1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775450122, COSV51562795; called by muse, mutect2, varscan2
- RIMS2 | c.3251C>G p.P1084R (on ENST00000666250 / NM_001348490.2; = p.P892R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/572 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.981); catalogued as COSV51654589; called by muse, mutect2, varscan2
- RIN3 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 229/491 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); catalogued as rs774441433; called by mutect2, varscan2
- SDK1 | c.4789A>T p.I1597L | Missense Mutation (SNP) | VAF 153/397 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs760213845, COSV67371273; called by muse, mutect2, varscan2
- SERINC2 | c.658G>A p.V220M (on ENST00000373709 / NM_178865.5; = p.V224M on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/619 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs1211669610; called by muse, mutect2, varscan2
- SLC39A7 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 150/558 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs201987088; called by muse, mutect2, varscan2
- SLC5A2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 116/612 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs148410166, CM034973; called by muse, varscan2
- SLIT2 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 119/401 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as rs147726667; called by muse, mutect2, varscan2
- SPTA1 | c.2625G>T p.K875N | Missense Mutation (SNP) | VAF 160/422 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100935039; called by muse, mutect2, varscan2
- SUCO | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 117/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304437874; called by muse, mutect2, varscan2
- SUGCT | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751540603, COSV59330454; called by muse, mutect2, varscan2
- TLR4 | c.1642G>T p.V548F (on ENST00000355622 / NM_138554.5; = p.V508F on NM_003266.4) | Missense Mutation (SNP) | VAF 198/275 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs868550156; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 152/248 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1485903955; called by muse, mutect2, varscan2
- UNC5B | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs983043539; called by muse, mutect2, varscan2
- UNC5D | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.499); catalogued as rs1337812064, COSV54777898; called by muse, mutect2, varscan2
- UTRN | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV62328694; called by muse, mutect2, varscan2
- VKORC1 | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 381/904 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM040500; called by muse, mutect2, varscan2
- XRN2 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV65869645; called by muse, mutect2, varscan2
- ZNF784 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 188/557 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1274374623, COSV57595223; called by muse, mutect2, varscan2
- ZNF862 | c.2774T>A p.V925D | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV56225841; called by muse, mutect2, varscan2
- ACADS | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2
- ACTRT2 | c.1054A>C p.S352R | Missense Mutation (SNP) | VAF 67/875 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2
- ANGEL2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 181/417 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANKRD11 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 138/370 reads (37%) | called by muse, mutect2, varscan2
- ANKRD44 | c.2860T>G p.L954V | Missense Mutation (SNP) | VAF 21/449 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANLN | c.3117T>G p.S1039R | Missense Mutation (SNP) | VAF 265/444 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATOH8 | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 18/533 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ATP9A | c.2150A>G p.N717S | Missense Mutation (SNP) | VAF 24/663 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2
- BCAT2 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 95/548 reads (17%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- C14orf93 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 141/243 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C20orf144 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 46/1300 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.178); called by muse, mutect2
- C2CD4D | c.437C>A p.P146Q | Missense Mutation (SNP) | VAF 414/846 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CCDC17 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 298/592 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- CCDC171 | c.1820T>C p.V607A | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CD300LF | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 27/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD99L2 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CDC37L1 | c.517A>C p.S173R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- CHMP4B | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 42/1187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- COG8 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 350/792 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE4 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 285/502 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CTSB | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 213/491 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CYLD | c.1586A>C p.K529T | Missense Mutation (SNP) | VAF 23/586 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2
- DBF4B | c.1622T>C p.L541P | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DEAF1 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- DENND2A | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- DOCK10 | c.5310_5311+2del p.X1770_splice | Splice Site (DEL) | VAF 25/233 reads (11%) | called by mutect2, pindel, varscan2
- DOCK10 | c.3854A>G p.D1285G | Missense Mutation (SNP) | VAF 114/137 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DOCK6 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 181/513 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- DOK6 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 228/229 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EPHB1 | c.2586G>T p.Q862H | Missense Mutation (SNP) | VAF 208/603 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ETNPPL | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- F8 | c.5960_5963del p.K1987Rfs*42 | Frame Shift Del (DEL) | VAF 61/268 reads (23%) | called by mutect2, pindel, varscan2
- FRAS1 | c.1679-1G>T p.X560_splice | Splice Site (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- FRY | c.6505A>T p.R2169W | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FSIP2 | c.20104T>C p.S6702P | Missense Mutation (SNP) | VAF 222/431 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD8 | c.1316A>G p.Q439R | Missense Mutation (SNP) | VAF 127/1076 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GCC2 | c.2707A>C p.I903L | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- GPR101 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 124/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H3C3 | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); called by muse, mutect2
- HHIPL1 | c.1160A>T p.E387V | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HYDIN | c.4247T>C p.V1416A | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGSF9B | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- ITGB7 | c.1861T>C p.C621R | Missense Mutation (SNP) | VAF 124/505 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANK2 | c.1663G>A p.A555T (on ENST00000586659 / NM_001379562.1; = p.A563T on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- KHDRBS3 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 147/474 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KIF21B | c.4007T>C p.V1336A (on ENST00000422435 / NM_001252100.2; = p.V1323A on NM_017596.4) | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2
- KLHDC4 | c.815A>T p.K272M | Missense Mutation (SNP) | VAF 54/548 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- KLK5 | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 82/288 reads (28%) | called by muse, varscan2
- KMO | c.269_272del p.L90Qfs*19 | Frame Shift Del (DEL) | VAF 134/295 reads (45%) | called by mutect2, pindel, varscan2
- LPA | c.5774T>C p.L1925P | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LTBP1 | c.2984G>T p.R995L (on ENST00000404816 / NM_206943.4; = p.R669L on NM_000627.4) | Missense Mutation (SNP) | VAF 148/237 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAGEL2 | c.2666A>C p.K889T | Missense Mutation (SNP) | VAF 263/637 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MANEAL | c.976T>G p.F326V (on ENST00000373045 / NM_001113482.1; = p.F104V on NM_152496.2) | Missense Mutation (SNP) | VAF 34/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP4K1 | c.240T>G p.S80R | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- MEGF9 | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- METTL16 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 24/718 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- MFN2 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MIDN | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 425/425 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMEL1 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 351/954 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MORC4 | c.2366del p.F789Sfs*27 | Frame Shift Del (DEL) | VAF 193/269 reads (72%) | called by mutect2, pindel, varscan2
- MROH1 | c.677T>G p.V226G | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- MRPL16 | c.168_171del p.P57Lfs*5 | Frame Shift Del (DEL) | VAF 45/158 reads (28%) | called by mutect2, pindel, varscan2
- MYORG | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 520/520 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NAA10 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 631/631 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NBAS | c.5570C>T p.T1857I | Missense Mutation (SNP) | VAF 128/379 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOS1 | c.3389_3390insAT p.L1131Cfs*40 | Frame Shift Ins (INS) | VAF 71/306 reads (23%) | called by mutect2, pindel, varscan2
- OR13D1 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T1 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 121/929 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- OR51B5 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52N4 | c.698C>A p.A233E | Missense Mutation (SNP) | VAF 272/273 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PAX1 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 628/873 reads (72%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA6 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 522/524 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PCDHB3 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 64/1053 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEG3 | c.2089A>T p.S697C | Missense Mutation (SNP) | VAF 220/447 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PGGT1B | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PGLYRP2 | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 82/1001 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2
- PLEKHG4 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 46/856 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- PNKD | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RAD52 | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RBFOX2 | c.471A>C p.E157D (on ENST00000438146 / NM_001349995.2; = p.E87D on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/612 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RCAN2 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 151/389 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RS1 | c.455G>C p.S152T | Missense Mutation (SNP) | VAF 46/719 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2
- SAMD9 | c.4252G>C p.V1418L | Missense Mutation (SNP) | VAF 73/439 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SBNO1 | c.1646T>C p.L549P (on ENST00000420886; = p.L548P on NM_018183.5) | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SELL | c.1003A>C p.S335R (on ENST00000650983; = p.S322R on NM_000655.5) | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2
- SH3PXD2A | c.2569T>A p.S857T (on ENST00000369774 / NM_001365079.1; = p.S829T on NM_014631.2) | Missense Mutation (SNP) | VAF 52/672 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2
- SHANK1 | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 253/509 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SHROOM4 | c.1124G>T p.R375I | Missense Mutation (SNP) | VAF 237/238 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SLC30A1 | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC34A1 | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 37/926 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC66A1 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 160/323 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SLCO1C1 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SMC1A | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 142/143 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SMCO1 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SP140 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 128/167 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.1811T>C p.V604A | Missense Mutation (SNP) | VAF 144/881 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TGFA | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- TGM2 | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132B | c.2104A>C p.S702R | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM200C | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 332/518 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNFRSF19 | c.968G>A p.C323Y | Missense Mutation (SNP) | VAF 181/598 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TOB2 | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 54/864 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2
- TRIM16L | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 278/570 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRIM59 | c.1170C>G p.F390L | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC4AP | c.613T>G p.L205V | Missense Mutation (SNP) | VAF 28/708 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- TTN | c.71700A>C p.E23900D (on ENST00000591111; = p.E16476D on NM_003319.4) | Missense Mutation (SNP) | VAF 68/600 reads (11%) | PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TTN | c.14603T>G p.V4868G (on ENST00000591111; = p.V3941G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/636 reads (5%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- USP34 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- UTRN | c.4570C>A p.L1524I | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VANGL2 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 217/474 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- VPS29 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.182); called by muse, mutect2
- WDFY1 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ZHX1 | c.2520A>C p.E840D | Missense Mutation (SNP) | VAF 52/1106 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- ZNF223 | c.1299T>A p.C433* | Nonsense Mutation (SNP) | VAF 29/334 reads (9%) | called by muse, mutect2
- ZNF248 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 385/673 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF251 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 437/669 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF469 | c.3010A>T p.S1004C | Missense Mutation (SNP) | VAF 24/810 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ZNF524 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 177/613 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF585B | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 259/563 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF622 | c.315del p.V106Wfs*3 | Frame Shift Del (DEL) | VAF 375/753 reads (50%) | called by mutect2, pindel, varscan2
- ZNF658 | c.754T>G p.F252V | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.039); called by muse, mutect2
- ABCA10 | c.786A>G p.R262= | Silent (SNP) | VAF 104/273 reads (38%) | catalogued as rs1165749028; called by muse, mutect2, varscan2
- ARHGAP9 | c.1428C>T p.A476= (on ENST00000393797 / NM_001319850.2; = p.A457= on NM_032496.4) | Silent (SNP) | VAF 222/1320 reads (17%) | catalogued as COSV57358616; called by muse, mutect2, varscan2
- ATG9B | c.2202A>G p.R734= | Silent (SNP) | VAF 55/390 reads (14%) | called by muse, mutect2, varscan2
- CDH8 | c.1686T>C p.N562= | Silent (SNP) | VAF 53/260 reads (20%) | called by muse, mutect2, varscan2
- COL3A1 | c.351T>A p.P117= | Silent (SNP) | VAF 24/395 reads (6%) | catalogued as COSV58592713; called by muse, mutect2
- CTNNBL1 | c.192C>T p.D64= | Silent (SNP) | VAF 107/576 reads (19%) | called by muse, mutect2, varscan2
- DLC1 | c.3243G>A p.T1081= (on ENST00000276297 / NM_001348081.2; = p.T644= on NM_006094.5) | Silent (SNP) | VAF 90/808 reads (11%) | catalogued as rs148109949; called by muse, mutect2, varscan2
- DNAAF5 | c.1062C>T p.F354= | Silent (SNP) | VAF 133/782 reads (17%) | called by muse, mutect2, varscan2
- DNAH9 | c.7923G>A p.P2641= | Silent (SNP) | VAF 516/516 reads (100%) | catalogued as rs765541256, COSV52349804; called by muse, mutect2, varscan2
- EIF4B | c.411A>G p.K137= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- FAM219B | c.6G>A p.A2= | Silent (SNP) | VAF 206/469 reads (44%) | catalogued as rs1315143788; called by muse, mutect2, varscan2
- FKBP9 | c.1686C>T p.D562= | Silent (SNP) | VAF 82/470 reads (17%) | catalogued as rs1562578747; called by muse, mutect2, varscan2
- FOXG1 | c.817C>T p.L273= | Silent (SNP) | VAF 158/579 reads (27%) | called by muse, mutect2, varscan2
- FRMPD4 | c.462T>G p.P154= | Silent (SNP) | VAF 36/414 reads (9%) | called by muse, mutect2
- FUCA1 | c.1062G>A p.R354= | Silent (SNP) | VAF 90/516 reads (17%) | called by muse, mutect2, varscan2
- GALNT13 | c.732T>G p.T244= | Silent (SNP) | VAF 148/328 reads (45%) | catalogued as COSV101222246; called by muse, mutect2, varscan2
- GFPT2 | c.1947G>A p.L649= | Silent (SNP) | VAF 142/563 reads (25%) | catalogued as COSV53811562; called by muse, mutect2, varscan2
- GLI3 | c.3315A>G p.Q1105= | Silent (SNP) | VAF 264/758 reads (35%) | called by muse, mutect2, varscan2
- GLI3 | c.1615A>C p.R539= | Silent (SNP) | VAF 204/376 reads (54%) | called by muse, mutect2, varscan2
- HEATR1 | c.531T>G p.T177= | Silent (SNP) | VAF 40/448 reads (9%) | called by muse, mutect2
- HGSNAT | c.270T>C p.S90= | Silent (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- HLA-G | c.222G>A p.P74= | Silent (SNP) | VAF 122/291 reads (42%) | called by muse, mutect2, varscan2
- JAM2 | c.582A>G p.T194= | Silent (SNP) | VAF 141/322 reads (44%) | called by muse, mutect2, varscan2
- KCNT2 | c.2727C>T p.I909= | Silent (SNP) | VAF 65/304 reads (21%) | called by muse, mutect2, varscan2
- KIF26A | c.3366C>T p.A1122= | Silent (SNP) | VAF 153/404 reads (38%) | catalogued as rs1180808620; called by muse, mutect2, varscan2
- KLF4 | c.399G>A p.S133= | Silent (SNP) | VAF 59/706 reads (8%) | catalogued as rs748996367; called by muse, mutect2
- LCOR | c.708A>G p.R236= | Silent (SNP) | VAF 32/384 reads (8%) | called by muse, mutect2
- LRP3 | c.1146C>T p.D382= | Silent (SNP) | VAF 362/626 reads (58%) | catalogued as rs756455692; called by muse, varscan2
- MACC1 | c.303T>C p.F101= | Silent (SNP) | VAF 108/284 reads (38%) | called by muse, mutect2, varscan2
- MARCHF11 | c.336G>A p.A112= | Silent (SNP) | VAF 118/1136 reads (10%) | catalogued as rs1026225474; called by muse, mutect2, varscan2
- MOXD1 | c.1668T>C p.A556= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as rs139724563; called by muse, mutect2, varscan2
- MROH5 | c.2379A>G p.Q793= | Silent (SNP) | VAF 46/754 reads (6%) | called by muse, mutect2
- MYO16 | c.1188G>A p.K396= | Silent (SNP) | VAF 76/283 reads (27%) | called by muse, mutect2, varscan2
- MYO18B | c.3957T>C p.F1319= | Silent (SNP) | VAF 179/384 reads (47%) | catalogued as COSV100125442; called by muse, mutect2, varscan2
- NCAPH2 | c.330C>T p.V110= | Silent (SNP) | VAF 287/545 reads (53%) | catalogued as rs752766206; called by muse, mutect2, varscan2
- NEK10 | c.2580C>T p.S860= | Silent (SNP) | VAF 201/335 reads (60%) | catalogued as rs766694769, COSV55357483; called by muse, mutect2, varscan2
- NFKBIB | c.534C>A p.A178= | Silent (SNP) | VAF 255/459 reads (56%) | called by muse, mutect2, varscan2
- NTRK2 | c.1620G>A p.L540= (on ENST00000323115 / NM_001369534.1; = p.L556= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/248 reads (17%) | called by muse, mutect2, varscan2
- OR2F1 | c.570G>T p.V190= | Silent (SNP) | VAF 49/281 reads (17%) | called by muse, mutect2, varscan2
- PAQR9 | c.807G>A p.E269= | Silent (SNP) | VAF 76/605 reads (13%) | catalogued as COSV61418198; called by muse, mutect2, varscan2
- PKP1 | c.1980G>A p.S660= | Silent (SNP) | VAF 267/498 reads (54%) | catalogued as rs753009686; called by muse, mutect2, varscan2
- PLPP3 | c.150C>T p.P50= | Silent (SNP) | VAF 139/284 reads (49%) | catalogued as rs779524153; called by muse, mutect2, varscan2
- PPIAL4G | c.33C>T p.T11= | Silent (SNP) | VAF 224/460 reads (49%) | catalogued as rs1465142768, COSV101344014; called by muse, mutect2, varscan2
- PTPRD | c.3804C>T p.I1268= | Silent (SNP) | VAF 197/198 reads (99%) | called by muse, mutect2, varscan2
- RIMBP2 | c.3156T>G p.P1052= | Silent (SNP) | VAF 80/176 reads (45%) | called by muse, mutect2, varscan2
- RPRD2 | c.1683T>A p.T561= | Silent (SNP) | VAF 27/484 reads (6%) | called by muse, mutect2
- SBF1 | c.1587A>G p.P529= | Silent (SNP) | VAF 48/942 reads (5%) | called by muse, mutect2
- SEC24B | c.3549G>A p.V1183= | Silent (SNP) | VAF 175/186 reads (94%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.672T>C p.I224= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV53584241; called by muse, mutect2
- SPG7 | c.1896C>T p.S632= (on ENST00000268704; = p.S639= on NM_003119.4) | Silent (SNP) | VAF 50/351 reads (14%) | catalogued as rs1459605717; called by muse, mutect2, varscan2
- SQSTM1 | c.579C>T p.F193= | Silent (SNP) | VAF 218/719 reads (30%) | catalogued as rs527602; called by muse, mutect2, varscan2
- STIL | c.1110T>G p.A370= | Silent (SNP) | VAF 20/331 reads (6%) | called by muse, mutect2
- TCERG1L | c.726C>T p.T242= | Silent (SNP) | VAF 355/723 reads (49%) | catalogued as rs377139494, COSV64047479; called by muse, mutect2, varscan2
- TENT5C | c.189C>T p.G63= | Silent (SNP) | VAF 181/369 reads (49%) | called by muse, mutect2, varscan2
- TGM7 | c.1761C>T p.I587= | Silent (SNP) | VAF 202/375 reads (54%) | catalogued as rs777829273; called by muse, mutect2, varscan2
- TMEM25 | c.408C>T p.G136= | Silent (SNP) | VAF 257/257 reads (100%) | catalogued as rs200064947; called by muse, mutect2, varscan2
- TRERF1 | c.1458A>G p.R486= | Silent (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- TRIM62 | c.954T>G p.A318= | Silent (SNP) | VAF 34/686 reads (5%) | catalogued as rs754613013; called by muse, mutect2
- TRMO | c.180G>A p.L60= | Silent (SNP) | VAF 88/324 reads (27%) | called by muse, mutect2, varscan2
- UBQLNL | c.753A>G p.P251= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- ZNF274 | c.892C>A p.R298= (on ENST00000610905; = p.R193= on NM_016324.3) | Silent (SNP) | VAF 172/349 reads (49%) | catalogued as rs764561877; called by muse, mutect2, varscan2
- ZNF530 | c.1785A>G p.R595= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ZNF717 | c.2055C>T p.V685= | Silent (SNP) | VAF 324/486 reads (67%) | called by muse, mutect2
- ARHGEF4 | c.1921+30C>T | Intron (SNP) | VAF 76/670 reads (11%) | called by muse, mutect2, varscan2
- CDCA7 | c.147+597C>G | Intron (SNP) | VAF 160/279 reads (57%) | called by muse, mutect2, varscan2
- CSH1 | c.456+11C>T | Intron (SNP) | VAF 135/595 reads (23%) | catalogued as rs766433019; called by muse, mutect2, varscan2
- DLG4 | c.787+49C>T | Intron (SNP) | VAF 291/603 reads (48%) | called by muse, mutect2, varscan2
- FAM227A | c.*3746C>T | 3'UTR (SNP) | VAF 81/368 reads (22%) | called by muse, mutect2, varscan2
- METTL11B | c.-1C>A | 5'UTR (SNP) | VAF 70/320 reads (22%) | called by muse, mutect2, varscan2
- OR5R1 | chr11:56413397 G>A | 3'Flank (SNP) | VAF 174/174 reads (100%) | catalogued as rs1042579595; called by muse, mutect2, varscan2
- PCDH17 | c.-1G>C | 5'UTR (SNP) | VAF 72/396 reads (18%) | called by muse, mutect2, varscan2
